Somatic mutation profile of tumor specimen TCGA-NC-A5HT-01A (aliquot TCGA-NC-A5HT-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HT, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 69.7 years (25,466 days).
Specimen TCGA-NC-A5HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f97bc3f1-c307-455c-84ea-260972ba53a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HT-10A (Blood Derived Normal), aliquot TCGA-NC-A5HT-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3e9da34-e175-45ea-879b-70b32d6a26d7

The open-access MAF lists 383 somatic variants for this specimen: 293 protein-altering or splice-affecting, 83 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 83, Nonsense Mutation 16, Frame Shift Del 11, Splice Site 8, Frame Shift Ins 4, Intron 4, Nonstop Mutation 2, 3'UTR 1, In Frame Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 56/184 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2*, pindel, varscan2*
- TTN | c.51869G>A p.W17290* (on ENST00000591111; = p.W9866* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as rs1060500526, COSV100620498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99367936; called by muse, mutect2, varscan2
- AADAC | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99233373; called by muse, mutect2, varscan2
- ABCA8 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99286348; called by muse, mutect2, varscan2
- ABCA9 | c.3134T>C p.I1045T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs144122311; called by muse, mutect2, varscan2
- ABHD10 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56324751, COSV99845102; called by muse, mutect2, varscan2
- AC097636.1 | c.152G>T p.R51M | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101469680; called by muse, mutect2, varscan2
- AC097636.1 | c.153G>T p.R51S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101469681; called by muse, mutect2, varscan2
- AC100868.1 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99226403; called by muse, mutect2, varscan2
- ACTN2 | c.1365G>T p.Q455H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV100856887; called by muse, mutect2, varscan2
- ACTN2 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100856888, COSV63975014; called by muse, mutect2, varscan2
- ACTRT2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs138316843; called by muse, mutect2, varscan2
- ADAM22 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.244); catalogued as COSV99717530, COSV99718654; called by muse, mutect2
- ADAM30 | c.824G>A p.R275K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV101023917; called by muse, mutect2, varscan2
- ADAMTS3 | c.3373G>C p.D1125H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99711525; called by muse, mutect2, varscan2
- ADARB2 | c.2098A>C p.K700Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184566; called by muse, mutect2, varscan2
- AGBL4 | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV100484438; called by muse, mutect2, varscan2
- AHNAK | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs140181767; called by muse, mutect2, varscan2
- AMER1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376626895, COSV57661462; called by muse, mutect2, varscan2
- ANKRD28 | c.2471G>T p.R824I | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101080793; called by muse, mutect2, varscan2
- ANKRD30A | c.2711G>T p.R904I (on ENST00000611781; = p.R848I on NM_052997.2) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV100653984; called by muse, mutect2, varscan2
- ANKRD44 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99985442; called by muse, mutect2, varscan2
- AQP3 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.437); catalogued as COSV99955631; called by muse, varscan2
- AQR | c.4103T>G p.M1368R | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99334278; called by muse, mutect2, varscan2
- ARIH2 | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | catalogued as COSV100711368; called by muse, mutect2, varscan2
- ARL5B | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101040347; called by muse, mutect2, varscan2
- ASMT | c.85T>A p.C29S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV101172496; called by muse, mutect2, varscan2
- ASXL2 | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55456670, COSV99711627; called by muse, mutect2, varscan2
- ATP11A | c.1060G>C p.V354L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99369257; called by muse, mutect2, varscan2
- ATR | c.7761+2T>G p.X2587_splice | Splice Site (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100638371; called by mutect2, varscan2
- ATXN1 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 88/337 reads (26%) | catalogued as COSV55225794, COSV99786939; called by muse, mutect2, varscan2
- BMERB1 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100252687, COSV100253187; called by muse, mutect2, varscan2
- BRINP3 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV100819097; called by muse, mutect2, varscan2
- C6 | c.1255A>T p.R419W | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99667408; called by muse, mutect2, varscan2
- CAMK1D | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV101123814; called by muse, mutect2, varscan2
- CCDC74B | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1174784529; called by muse, varscan2
- CCL28 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100742064; called by muse, mutect2, varscan2
- CCP110 | c.1111A>G p.M371V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101195305; called by muse, mutect2, varscan2
- CD300A | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | catalogued as COSV100177944; called by muse, mutect2, varscan2
- CDH10 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100052183; called by muse, mutect2, varscan2
- CDH26 | c.1081_1083del p.E361del | In Frame Del (DEL) | VAF 46/153 reads (30%) | catalogued as rs1442433927; called by pindel, varscan2
- CELF2 | c.99C>G p.D33E (on ENST00000416382 / NM_001025077.3; = p.D40E on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.945); catalogued as COSV100257875; called by muse, mutect2, varscan2
- CELF2 | c.1198A>T p.T400S (on ENST00000416382 / NM_001025077.3; = p.T413S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100257879; called by muse, mutect2, varscan2
- CHRM2 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.044); catalogued as COSV100281601; called by muse, mutect2, varscan2
- CHRNA6 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775552140, COSV99373299; called by muse, mutect2, varscan2
- CIC | c.3154T>G p.F1052V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV99359907; called by muse, mutect2
- CKAP5 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.777); catalogued as COSV100371021; called by muse, mutect2, varscan2
- CNBD1 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV72976839; called by muse, mutect2, varscan2
- CNBD1 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.665); catalogued as COSV72976180; called by muse, mutect2, varscan2
- CNTN3 | c.2321A>T p.Y774F | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV99725233; called by muse, mutect2, varscan2
- COL11A1 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs752749747, COSV100617349, COSV62180341; called by muse, mutect2, varscan2
- COL24A1 | c.49del p.A17Qfs*26 | Frame Shift Del (DEL) | VAF 69/238 reads (29%) | catalogued as COSV65310871; called by mutect2, pindel, varscan2
- COL4A4 | c.3719C>T p.P1240L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100307275; called by muse, mutect2, varscan2
- COL5A3 | c.4206G>T p.K1402N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99319279; called by muse, mutect2, varscan2
- COLEC12 | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101232112; called by muse, mutect2, varscan2
- CR2 | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV100889675, COSV65507413; called by muse, mutect2, varscan2
- CSH1 | c.422A>G p.K141R | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV100298389; called by muse, mutect2, varscan2
- CSMD3 | c.8872G>T p.V2958L (on ENST00000297405 / NM_001363185.1; = p.V2789L on NM_052900.3) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99839667; called by muse, mutect2, varscan2
- CSMD3 | c.7625G>T p.G2542V (on ENST00000297405 / NM_001363185.1; = p.G2438V on NM_052900.3) | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99839668; called by muse, varscan2
- DFFA | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100986632, COSV100986669; called by muse, mutect2, varscan2
- DNAH8 | c.8779C>A p.H2927N | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100546285; called by muse, mutect2, varscan2
- DPP8 | c.1409C>G p.S470C (on ENST00000341861 / NM_001320875.2; = p.S454C on NM_017743.6) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100202466; called by muse, mutect2, varscan2
- DUSP2 | c.906del p.Q303Sfs*80 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as COSV99997070; called by mutect2, pindel, varscan2
- EFCAB5 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100300474; called by muse, mutect2, varscan2
- EIF5A | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.223); catalogued as COSV100223118; called by muse, mutect2, varscan2
- ELAVL2 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99806639; called by muse, mutect2
- EME1 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs748216992, COSV56815068, COSV56815349; called by muse, mutect2, varscan2
- ENPEP | c.1895A>C p.E632A | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.457); catalogued as COSV99487814; called by muse, mutect2, varscan2
- EPB41L3 | c.2656T>A p.F886I | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.028); catalogued as COSV100549694; called by muse, mutect2, varscan2
- ERBB4 | c.3284A>T p.Q1095L | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV100726442; called by muse, mutect2, varscan2
- ERBB4 | c.2353G>C p.G785R | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100726444; called by muse, mutect2, varscan2
- EVC | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV53836410, COSV99382164; called by muse, mutect2, varscan2
- FANCF | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 105/304 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs992569572, COSV100541851; called by muse, mutect2, varscan2
- FAT2 | c.8255G>T p.R2752M | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV55814945, COSV99943520; called by muse, mutect2, varscan2
- FBN3 | c.2870C>T p.P957L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV54471444; called by muse, mutect2, varscan2
- FBXW2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61597019; called by muse, mutect2, varscan2
- FCRL3 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs775482909, COSV100943395; called by muse, mutect2, varscan2
- FCRL4 | c.1414G>C p.G472R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV99620067, COSV99620073; called by muse, mutect2, varscan2
- FGF6 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99960326; called by muse, mutect2
- FRMPD1 | c.1958G>C p.S653T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV100899592; called by muse, mutect2, varscan2
- FRMPD3 | c.2703G>C p.Q901H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV99346629; called by muse, mutect2, varscan2
- FZD9 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 112/337 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100750870; called by muse, mutect2, varscan2
- FZD9 | c.1774T>C p.*592Qext*24 | Nonstop Mutation (SNP) | VAF 96/283 reads (34%) | catalogued as COSV100289908; called by muse, mutect2, varscan2
- GABRA2 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as COSV100734542; called by muse, mutect2, varscan2
- GABRA4 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.158); catalogued as rs1350775778, COSV99974286; called by muse, mutect2, varscan2
- GABRA5 | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100165447; called by muse, mutect2, varscan2
- GABRG1 | c.888A>T p.K296N | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99778418; called by muse, mutect2, varscan2
- GAL3ST3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.848); catalogued as rs900535564; called by muse, mutect2
- GALNT3 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV101204980, COSV67061410; called by muse, mutect2, varscan2
- GAP43 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV100525743; called by muse, mutect2, varscan2
- GDF3 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100325212, COSV100325339; called by muse, mutect2, varscan2
- GDPD5 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.195); catalogued as COSV100409389; called by muse, mutect2, varscan2
- GFPT2 | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53807485, COSV99517868; called by muse, mutect2, varscan2
- GRID2 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943304; called by muse, mutect2, varscan2
- GRIK3 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs768148773, COSV100901773, COSV100902175; called by muse, mutect2, varscan2
- HAL | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701542; called by muse, mutect2
- HCN1 | c.2171C>A p.A724D | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); catalogued as COSV100301221; called by muse, mutect2, varscan2
- HDC | c.950+1G>T p.X317_splice | Splice Site (SNP) | VAF 30/102 reads (29%) | catalogued as COSV99984172, COSV99984409; called by muse, mutect2, varscan2
- HDC | c.950G>T p.W317L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99984175; called by muse, mutect2, varscan2
- HEXD | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as CM1410440, COSV100027508, COSV100027833; called by muse, mutect2, varscan2
- HS3ST4 | c.872T>A p.V291E | Missense Mutation (SNP) | VAF 98/414 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1227471626, COSV100502057; called by muse, mutect2, varscan2
- HSP90AB1 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 159/336 reads (47%) | catalogued as COSV100807138; called by muse, mutect2, varscan2
- HSP90B1 | c.1801A>G p.S601G | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100236627; called by muse, mutect2, varscan2
- HSPD1 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as COSV100798411; called by muse, mutect2, varscan2
- IL12RB1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV100443115; called by muse, mutect2, varscan2
- IMP4 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52093123, COSV99383788; called by muse, mutect2, varscan2
- INPP4A | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50798693; called by muse, mutect2, varscan2
- INTS3 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100016276, COSV59682212; called by muse, mutect2, varscan2
- INTS5 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs997572438, COSV100399708; called by muse, mutect2, varscan2
- IQGAP2 | c.4679A>G p.N1560S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99167688; called by muse, mutect2, varscan2
- IQSEC2 | c.1837G>T p.G613C (on ENST00000642864 / NM_001111125.3; = p.G408C on NM_015075.2) | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64725824; called by muse, mutect2, varscan2
- IQUB | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV100227226; called by muse, mutect2, varscan2
- ITCH | c.2243G>A p.R748Q (on ENST00000262650 / NM_001257137.3; = p.R707Q on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99392771; called by muse, mutect2, varscan2
- ITGA8 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 46/90 reads (51%) | catalogued as rs1376907527, COSV65226521; called by muse, mutect2, varscan2
- IZUMO1 | c.471C>G p.H157Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs779418465, COSV99710926; called by muse, mutect2, varscan2
- KCNG1 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100857131; called by muse, mutect2, varscan2
- KCNT1 | c.214T>G p.Y72D (on ENST00000488444; = p.Y91D on NM_020822.3) | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99706130; called by muse, mutect2, varscan2
- KCNT2 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV54109401, COSV99655117; called by muse, mutect2, varscan2
- KCTD8 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 131/403 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV100759766, COSV63598657; called by muse, mutect2, varscan2
- KDR | c.1859G>A p.S620N | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.213); catalogued as COSV99818150; called by muse, mutect2, varscan2
- KIAA1958 | c.1627C>A p.Q543K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100516276; called by muse, mutect2
- KIAA1958 | c.1628A>T p.Q543L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100516278; called by muse, mutect2
- KMT2D | c.5743G>T p.E1915* | Nonsense Mutation (SNP) | VAF 62/153 reads (41%) | catalogued as COSV99983773; called by muse, mutect2, varscan2
- KREMEN2 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99566984; called by muse, mutect2, varscan2
- KRI1 | c.1579A>G p.T527A | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100470255; called by muse, mutect2, varscan2
- KRTAP24-1 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV100447486; called by muse, mutect2, varscan2
- LAMA1 | c.4429G>T p.D1477Y | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101056947; called by muse, mutect2, varscan2
- LARGE1 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs543626511, COSV100505893; called by muse, mutect2, varscan2
- LARP1B | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 53/226 reads (23%) | catalogued as rs749514879, COSV52797191; called by muse, mutect2, varscan2
- LCA5L | c.779T>A p.L260H | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903749; called by muse, mutect2, varscan2
- LCT | c.2815C>A p.P939T | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51553123; called by muse, mutect2, varscan2
- LIAS | c.259G>T p.G87W (on ENST00000261434 / NM_001363700.2; = p.W118L on NM_006859.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99787767; called by muse, mutect2, varscan2
- LPA | c.4475C>T p.P1492L | Missense Mutation (SNP) | VAF 79/89 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV60299054; called by muse, mutect2, varscan2
- LPAR4 | c.997C>A p.L333M | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.288); catalogued as COSV101425141; called by muse, mutect2, varscan2
- LRRC4B | c.717C>A p.N239K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975985; called by muse, mutect2, varscan2
- LRRC7 | c.2596C>T p.H866Y (on ENST00000651989 / NM_001370785.2; = p.H833Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (0.83); PolyPhen possibly damaging (0.606); catalogued as COSV99228091; called by muse, mutect2, varscan2
- LRRTM1 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99702820; called by muse, mutect2, varscan2
- MC2R | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV100563087; called by muse, mutect2, varscan2
- ME1 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100866592; called by muse, mutect2, varscan2
- MEGF10 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.145); catalogued as COSV57244268, COSV99175120; called by muse, mutect2, varscan2
- METTL24 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100133487; called by muse, mutect2, varscan2
- MLXIPL | c.2446C>A p.L816M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100515439; called by muse, mutect2, varscan2
- MORC4 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV99717392; called by muse, mutect2, varscan2
- MSRB3 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs199788089, COSV100378071; called by muse, mutect2, varscan2
- MTTP | c.959T>A p.L320H | Missense Mutation (SNP) | VAF 126/217 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645379; called by muse, mutect2, varscan2
- MUC16 | c.37244C>A p.T12415N | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV101200466; called by muse, mutect2, varscan2
- MUC20 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as COSV57849031; called by muse, mutect2, varscan2
- MYNN | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62991399; called by muse, mutect2, varscan2
- MYOM3 | c.2990T>A p.L997Q | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV100293227; called by muse, mutect2, varscan2
- MYOZ3 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.39); PolyPhen benign (0.093); catalogued as COSV99770803; called by muse, varscan2
- NALCN | c.688T>G p.S230A | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV99216311; called by muse, mutect2, varscan2
- NCAN | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 125/336 reads (37%) | catalogued as COSV99387764; called by muse, mutect2, varscan2
- NCAN | c.3427A>C p.T1143P | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV99387766; called by muse, mutect2, varscan2
- NEXMIF | c.79+1G>C p.X27_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99281234; called by muse, mutect2
- NFATC1 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99502102; called by muse, mutect2, varscan2
- NIPSNAP3A | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV101046438; called by muse, mutect2, varscan2
- NKAPL | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100642552; called by muse, mutect2, varscan2
- NNT | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as CM125558, COSV99239216; called by muse, mutect2, varscan2
- NOCT | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 79/118 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV99763917; called by muse, mutect2, varscan2
- NSD1 | c.5713T>A p.C1905S | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100729584; called by muse, mutect2, varscan2
- NTRK1 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100693572; called by muse, mutect2, varscan2
- OR10H1 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100612450; called by muse, mutect2, varscan2
- OR10K2 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV100149562; called by muse, mutect2, varscan2
- OR1L1 | c.883C>A p.L295I (on ENST00000373686; = p.L245I on NM_001005236.3) | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV100542226; called by muse, mutect2, varscan2
- OR2M4 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV60709308; called by muse, mutect2, varscan2
- OR4C3 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100168043; called by muse, mutect2, varscan2
- OR5I1 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100041180, COSV56887019; called by muse, mutect2, varscan2
- OR9Q2 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs772085828, COSV100285478; called by muse, mutect2, varscan2
- OXA1L | c.209G>T p.R70L (on ENST00000285848; = p.R10L on NM_005015.5) | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV99591219; called by muse, mutect2, varscan2
- PARP14 | c.4019C>A p.P1340Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV101506307, COSV101506370; called by muse, mutect2, varscan2
- PCDHA12 | c.1304T>A p.L435Q | Missense Mutation (SNP) | VAF 137/227 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100252005; called by muse, mutect2, varscan2
- PCDHGA8 | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV99542022; called by muse, mutect2, varscan2
- PDGFC | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV56848247, COSV99925727; called by muse, mutect2, varscan2
- PEG3 | c.2483G>C p.R828T | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV99689564; called by muse, mutect2, varscan2
- PFKFB3 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 46/212 reads (22%) | PolyPhen benign (0.014); catalogued as COSV57988012; called by muse, mutect2, varscan2
- PGR | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99678666; called by muse, mutect2, varscan2
- PIK3CG | c.1679C>A p.A560D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV100783012; called by muse, mutect2, varscan2
- PIKFYVE | c.3944G>T p.W1315L | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52243714; called by muse, mutect2, varscan2
- PKD1L1 | c.3499T>A p.Y1167N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99220577; called by muse, mutect2, varscan2
- PLEKHG7 | c.1162A>T p.S388C | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV100760144; called by muse, mutect2, varscan2
- PLEKHO1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV99215261; called by muse, mutect2, varscan2
- PLSCR4 | c.452A>C p.Q151P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61607640; called by muse, mutect2, varscan2
- PLXND1 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.161); catalogued as COSV100140069; called by muse, mutect2, varscan2
- POLG | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 242/389 reads (62%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as COSV99174916; called by muse, mutect2, varscan2
- POU6F2 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101302772; called by muse, mutect2, varscan2
- PPM1B | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.059); catalogued as COSV99175845; called by muse, mutect2
- PPP1R9A | c.2840C>A p.P947Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.239); catalogued as COSV99196403; called by muse, mutect2, varscan2
- PRDM16 | c.699C>G p.D233E | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99577643; called by muse, mutect2, varscan2
- PRDM9 | c.2566G>A p.G856R | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as COSV99690677, COSV99690731; called by muse, mutect2, varscan2
- PREX2 | c.1443+1G>T p.X481_splice | Splice Site (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99905761; called by muse, mutect2, varscan2
- PRICKLE2 | c.1115C>A p.P372H (on ENST00000295902; = p.P316H on NM_198859.4) | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99897643; called by muse, mutect2, varscan2
- PTCHD4 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100261224; called by muse, mutect2, varscan2
- PTPRT | c.3204G>T p.Q1068H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100628688, COSV61959426; called by muse, mutect2, varscan2
- PTPRZ1 | c.4395T>G p.S1465R | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.178); catalogued as COSV101100460; called by muse, mutect2, varscan2
- PUS7L | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV100786565; called by muse, varscan2
- PXDNL | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1554536413, COSV62485656; called by muse, mutect2, varscan2
- PXDNL | c.225T>A p.N75K | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100684860; called by muse, mutect2, varscan2
- RALYL | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.756); catalogued as rs1253837488, COSV72820527; called by muse, mutect2, varscan2
- RASL12 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.888); catalogued as COSV99585054; called by muse, mutect2, varscan2
- REG1A | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 135/449 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99286852; called by muse, mutect2, varscan2
- RELN | c.8029G>A p.A2677T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.356); catalogued as rs747571208, COSV58987976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV1 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.13); catalogued as COSV99301171; called by muse, mutect2, varscan2
- RIMS2 | c.1909C>A p.P637T (on ENST00000666250 / NM_001348490.2; = p.P445T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176579; called by muse, mutect2, varscan2
- RMDN1 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs1026914855, COSV52203516, COSV52204039; called by muse, mutect2
- RPS11 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99569425; called by muse, mutect2, varscan2
- RUNX1T1 | c.1418G>A p.R473Q (on ENST00000265814 / NM_001198628.1; = p.R446Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs774408067, COSV56146644; called by muse, mutect2, varscan2
- RUNX2 | c.1316C>A p.T439N (on ENST00000371438; = p.T417N on NM_001015051.3) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100767564, COSV104420859; called by muse, mutect2, varscan2
- SAG | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101300688; called by muse, mutect2, varscan2
- SCN1A | c.4735G>C p.V1579L (on ENST00000303395 / NM_001202435.3; = p.V1568L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100321144; called by muse, mutect2, varscan2
- SCN7A | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs559936352, COSV101313343, COSV69270088; called by muse, mutect2, varscan2
- SIGLEC12 | c.986T>C p.L329P (on ENST00000291707 / NM_053003.4; = p.L211P on NM_033329.2) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389466; called by muse, mutect2, varscan2
- SIRT1 | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99281910; called by muse, mutect2, varscan2
- SLC12A1 | c.1784C>G p.P595R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101118984; called by muse, mutect2, varscan2
- SLC17A6 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99581894; called by muse, mutect2, varscan2
- SLC17A8 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100035686; called by muse, mutect2, varscan2
- SLC30A8 | c.271+2T>A p.X91_splice | Splice Site (SNP) | VAF 85/145 reads (59%) | catalogued as COSV101438613; called by muse, mutect2, varscan2
- SLC7A13 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV99878772, COSV99879205; called by muse, mutect2, varscan2
- SLCO6A1 | c.1815-2A>T p.X605_splice | Splice Site (SNP) | VAF 32/58 reads (55%) | catalogued as COSV101134625; called by muse, mutect2, varscan2
- SLITRK1 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV101000010, COSV65674775; called by muse, mutect2, varscan2
- SOD3 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464031376, COSV101181102; called by muse, mutect2, varscan2
- SORCS3 | c.1116G>T p.R372S | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV63826320; called by muse, mutect2, varscan2
- SPAG17 | c.5153C>A p.S1718* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as COSV100309676; called by muse, mutect2, varscan2
- SPATA31D1 | c.557T>A p.L186Q | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as COSV100782903; called by muse, mutect2, varscan2
- SPTA1 | c.6838T>G p.Y2280D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100935192; called by muse, mutect2, varscan2
- SSTR3 | c.1109T>G p.M370R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1385546860, COSV100142751; called by muse, mutect2, varscan2
- STIM1 | c.696C>G p.I232M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100330857; called by muse, mutect2, varscan2
- STIM2 | c.1190C>G p.T397S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV99402962; called by muse, mutect2, varscan2
- SYNPO2 | c.1760G>A p.R587K | Missense Mutation (SNP) | VAF 139/177 reads (79%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV100205977, COSV100206059; called by muse, mutect2, varscan2
- SZT2 | c.7471G>C p.E2491Q (on ENST00000634258 / NM_001365999.1; = p.E2434Q on NM_015284.4) | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV100987476; called by muse, mutect2, varscan2
- TCF20 | c.3985C>T p.P1329S | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100166760; called by muse, mutect2, varscan2
- TCF7L1 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs41289945, COSV99964340, COSV99964543; called by muse, mutect2, varscan2
- TECRL | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101169152; called by muse, mutect2, varscan2
- TGFBR1 | c.1256-1G>A p.X419_splice | Splice Site (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100895401; called by muse, mutect2, varscan2
- TJP2 | c.995T>C p.M332T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV99601430; called by muse, mutect2, varscan2
- TMA7 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV101194495; called by muse, mutect2, varscan2
- TMEM144 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.575); catalogued as COSV99646901; called by muse, mutect2, varscan2
- TMEM186 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs1376191417, COSV99191164; called by muse, mutect2, varscan2
- TNFRSF11A | c.738G>T p.L246F | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99500360; called by muse, mutect2, varscan2
- TP53 | c.533del p.H178Pfs*69 | Frame Shift Del (DEL) | VAF 41/62 reads (66%) | catalogued as COSV52689182, COSV53235050, COSV53281657; called by mutect2, varscan2
- TPBG | c.1186A>T p.M396L | Missense Mutation (SNP) | VAF 104/191 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100869792, COSV63882759; called by muse, mutect2, varscan2
- TPTE | c.1476C>G p.C492W (on ENST00000618007 / NM_199261.4; = p.C474W on NM_199259.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1431634382; called by muse, mutect2, varscan2
- TRAK1 | c.2769G>T p.M923I | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100565734; called by muse, mutect2, varscan2
- TRANK1 | c.6470G>A p.C2157Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100083712; called by muse, mutect2, varscan2
- TRIM60 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100594069; called by muse, mutect2, varscan2
- TRPM2 | c.2657G>T p.R886M | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs763579735, COSV100309063; called by muse, mutect2, varscan2
- TRPM3 | c.413C>A p.T138K (on ENST00000357533 / NM_001366142.2; = p.T107K on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100625118; called by muse, mutect2, varscan2
- TTN | c.67732C>T p.P22578S (on ENST00000591111; = p.P15154S on NM_003319.4) | Missense Mutation (SNP) | VAF 61/166 reads (37%) | PolyPhen possibly damaging (0.676); catalogued as COSV100620496; called by muse, mutect2, varscan2
- UNC79 | c.5374G>A p.E1792K (on ENST00000393151 / NM_001346218.2; = p.E1615K on NM_020818.5) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs199539496, COSV56386717; called by muse, mutect2, varscan2
- USH2A | c.11273G>T p.S3758I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100238348; called by muse, mutect2, varscan2
- USP3 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99165740; called by muse, mutect2, varscan2
- VEPH1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100747587; called by muse, mutect2, varscan2
- VN1R2 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV100448060; called by muse, mutect2, varscan2
- VTI1A | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101261390; called by muse, mutect2, varscan2
- WDR18 | c.15G>T p.M5I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99242935; called by muse, mutect2, varscan2
- ZC3H12D | c.1251C>A p.H417Q | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV101116999; called by muse, mutect2, varscan2
- ZNF100 | c.1483A>T p.N495Y | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV99974157; called by muse, mutect2, varscan2
- ZNF257 | c.1104A>T p.K368N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101448126; called by muse, mutect2, varscan2
- ZNF333 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99469354; called by muse, mutect2, varscan2
- ZNF33A | c.1592A>T p.K531I (on ENST00000458705 / NM_006974.3; = p.K532I on NM_006954.2) | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100276009; called by muse, mutect2, varscan2
- ZNF341 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV61010653; called by muse, mutect2, varscan2
- ZNF341 | c.1475A>G p.E492G (on ENST00000375200 / NM_001282935.1; = p.E485G on NM_032819.4) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100677930, COSV61011150; called by muse, mutect2
- ZNF425 | c.2200G>T p.V734L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100955528, COSV100955617; called by muse, mutect2, varscan2
- ZNF43 | c.2231A>T p.N744I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.242); catalogued as COSV100731878; called by muse, mutect2, varscan2
- ZNF521 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as rs571709268, COSV100832718, COSV64121612; called by muse, mutect2, varscan2
- ZNF707 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs929816453, COSV100690678; called by muse, mutect2, varscan2
- ZNF711 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV99341328; called by muse, mutect2, varscan2
- ZNF790 | c.1331A>G p.H444R | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100764858, COSV63211914; called by muse, mutect2, varscan2
- ZNF804A | c.3406C>G p.P1136A | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100168885, COSV100170672; called by muse, mutect2, varscan2
- ZNF835 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as COSV101606373; called by muse, mutect2, varscan2
- ZNF99 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101233883; called by muse, mutect2, varscan2
- ZWINT | c.56T>A p.V19E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100571538; called by muse, mutect2
- BOP1 | c.1979G>A p.R660K | Missense Mutation (SNP) | VAF 170/283 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- DENND1B | c.2113del p.E705Kfs*3 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | called by mutect2, pindel, varscan2
- DISP1 | c.2124del p.V709Yfs*20 | Frame Shift Del (DEL) | VAF 53/202 reads (26%) | called by mutect2, pindel, varscan2
- EPHA4 | c.20del p.F7Sfs*40 | Frame Shift Del (DEL) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- GAGE1 | c.206-1G>T p.X69_splice | Splice Site (SNP) | VAF 63/198 reads (32%) | called by muse, mutect2, varscan2
- GAS2L2 | c.1567A>T p.T523S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGKV1D-13 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- IZUMO2 | c.157_158del p.A53Rfs*46 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by pindel, varscan2
- LATS1 | c.248dup p.N83Kfs*9 | Frame Shift Ins (INS) | VAF 113/222 reads (51%) | called by mutect2, pindel, varscan2
- LNPK | c.843_844del p.H282* | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | called by pindel, varscan2
- NTRK3 | c.2388del p.E798Rfs*18 (on ENST00000360948 / NM_001012338.2; = p.E784Rfs*18 on NM_002530.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel*, varscan2
- NUMBL | c.597_599dup p.Q200dup | In Frame Ins (INS) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1425G>T p.*475Yext*1 | Nonstop Mutation (SNP) | VAF 51/149 reads (34%) | called by muse, mutect2, varscan2
- SH3RF1 | c.518_519insAA p.H173Qfs*38 | Frame Shift Ins (INS) | VAF 55/262 reads (21%) | called by mutect2, pindel, varscan2
- STXBP5L | c.2073dup p.P692Tfs*22 | Frame Shift Ins (INS) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- TFPT | c.248dup p.A84Gfs*47 | Frame Shift Ins (INS) | VAF 62/216 reads (29%) | called by mutect2, pindel, varscan2
- TMEM236 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAV12-2 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 87/301 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- UVSSA | c.2025del p.V676Sfs*10 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | called by mutect2, pindel, varscan2
- VN1R5 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 111/376 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- AATK | c.174C>A p.G58= | Silent (SNP) | VAF 94/122 reads (77%) | catalogued as rs202067944, COSV100452946; called by muse, mutect2, varscan2
- ABCA2 | c.1752C>G p.L584= (on ENST00000614293; = p.L554= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV99688013; called by muse, mutect2, varscan2
- ABCA7 | c.5763G>T p.R1921= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV99566268; called by muse, mutect2, varscan2
- ACOT11 | c.69G>T p.R23= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100650691; called by muse, mutect2, varscan2
- ADCY2 | c.2329C>T p.L777= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV100603345; called by muse, mutect2, varscan2
- ALPG | c.1515G>T p.A505= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs754903544, COSV99779397; called by muse, mutect2, varscan2
- ARID2 | c.5307A>C p.R1769= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as COSV100536511; called by muse, mutect2, varscan2
- ASTN1 | c.2139G>A p.G713= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as rs370818449, COSV99922378; called by muse, mutect2, varscan2
- ASXL3 | c.2361C>G p.S787= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99325633; called by muse, mutect2, varscan2
- BNIP3 | c.597T>C p.F199= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as rs755572711, COSV100893248; called by muse, mutect2, varscan2
- C2CD2L | c.1707G>A p.G569= | Silent (SNP) | VAF 290/372 reads (78%) | catalogued as COSV100371346; called by muse, mutect2, varscan2
- CACNG7 | c.438G>T p.V146= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as rs1371791169, COSV55814289, COSV99712134; called by muse, mutect2, varscan2
- CDH23 | c.2328C>A p.P776= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1261043074, COSV99822214; called by muse, mutect2
- CEP152 | c.3840C>T p.D1280= (on ENST00000380950 / NM_001194998.2; = p.D1224= on NM_014985.4) | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as COSV100358966; called by muse, mutect2, varscan2
- CLEC4F | c.510G>A p.R170= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs376751119; called by muse, mutect2, varscan2
- CPXM1 | c.468C>T p.G156= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs749022279, COSV101013686, COSV66045120; called by muse, mutect2, varscan2
- CRACD | c.2749C>A p.R917= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs779771309, COSV99949602; called by muse, mutect2, varscan2
- CREBZF | c.567C>T p.S189= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99476380; called by muse, mutect2, varscan2
- CSMD3 | c.3300C>A p.T1100= (on ENST00000297405 / NM_001363185.1; = p.T996= on NM_052900.3) | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV99839669; called by muse, mutect2, varscan2
- DZIP1L | c.384G>A p.E128= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs779954284, COSV100551511; called by muse, mutect2, varscan2
- ECM2 | c.912C>T p.S304= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as rs1206959524, COSV100755928; called by muse, mutect2, varscan2
- FADS3 | c.756G>A p.K252= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as COSV99605395; called by muse, mutect2, varscan2
- FUT1 | c.183G>T p.A61= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV55810058, COSV99711504; called by muse, mutect2, varscan2
- GALK2 | c.903C>T p.C301= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV100509028; called by muse, mutect2, varscan2
- GBA3 | c.228C>T p.F76= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as COSV101545535; called by muse, mutect2, varscan2
- GRTP1 | c.777G>T p.S259= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs748932612, COSV100208680; called by muse, mutect2, varscan2
- HNRNPD | c.1030A>C p.R344= (on ENST00000313899 / NM_031370.3; = p.R295= on NM_002138.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100002998; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.57C>G p.S19= | Silent (SNP) | VAF 66/299 reads (22%) | called by muse, mutect2, varscan2
- KAZN | c.600G>T p.L200= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs147925852; called by muse, mutect2, varscan2
- KCNH6 | c.1095C>T p.S365= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs773843120, COSV100121148; called by muse, mutect2, varscan2
- KIF2B | c.1638T>C p.D546= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV99275744; called by muse, mutect2, varscan2
- KIF3B | c.1257A>G p.E419= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100996416; called by muse, mutect2
- KIR3DL3 | c.807G>T p.V269= | Silent (SNP) | VAF 85/237 reads (36%) | called by muse, mutect2, varscan2
- KLC4 | c.1053C>A p.G351= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99432227; called by muse, mutect2, varscan2
- LAMA2 | c.1350T>G p.G450= | Silent (SNP) | VAF 63/93 reads (68%) | catalogued as COSV101370625; called by muse, mutect2, varscan2
- LIN7A | c.279A>T p.T93= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99692396; called by muse, mutect2
- LRRC66 | c.2031G>T p.L677= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100603027; called by muse, mutect2, varscan2
- LRRK1 | c.1818C>T p.T606= | Silent (SNP) | VAF 37/167 reads (22%) | catalogued as COSV99441391; called by muse, mutect2, varscan2
- MBD1 | c.42C>A p.G14= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99496695; called by muse, mutect2, varscan2
- MEGF8 | c.7515C>T p.S2505= (on ENST00000251268 / NM_001271938.2; = p.S2438= on NM_001410.3) | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99237632; called by mutect2, varscan2
- MSH4 | c.72C>A p.R24= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV99592048; called by muse, mutect2, varscan2
- MSX2 | c.777G>T p.V259= | Silent (SNP) | VAF 48/75 reads (64%) | catalogued as COSV99496907; called by muse, mutect2, varscan2
- MYBBP1A | c.1701G>C p.A567= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV99626478; called by muse, mutect2, varscan2
- NIPBL | c.6927A>G p.L2309= | Silent (SNP) | VAF 182/359 reads (51%) | catalogued as COSV99241427; called by muse, mutect2, varscan2
- NOS1 | c.1803C>T p.R601= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs371959195; called by muse, varscan2
- NOSTRIN | c.1335C>T p.A445= (on ENST00000317647 / NM_001039724.4; = p.A367= on NM_052946.3) | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs757389670, COSV100473811; called by muse, mutect2, varscan2
- NYAP1 | c.1413G>T p.T471= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100278577, COSV55722818; called by muse, varscan2
- OR5A1 | c.426C>A p.G142= | Silent (SNP) | VAF 170/418 reads (41%) | catalogued as COSV100118427, COSV57376835; called by muse, mutect2, varscan2
- OR8D4 | c.78C>G p.P26= | Silent (SNP) | VAF 105/137 reads (77%) | catalogued as COSV100361688, COSV100361868; called by muse, mutect2, varscan2
- PIGC | c.714A>T p.S238= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99278286; called by muse, mutect2, varscan2
- PRSS1 | c.615C>A p.V205= | Silent (SNP) | VAF 43/178 reads (24%) | catalogued as COSV100298147; called by muse, varscan2
- PSTPIP1 | c.1089G>A p.E363= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs781747543, COSV99143784; called by muse, mutect2, varscan2
- PTPRD | c.5448C>A p.S1816= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as COSV100645563; called by muse, mutect2, varscan2
- RASA2 | c.1620C>T p.L540= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs367958097, COSV99656427; called by muse, mutect2, varscan2
- RC3H1 | c.1977A>G p.P659= | Silent (SNP) | VAF 62/178 reads (35%) | catalogued as COSV99281535; called by muse, mutect2, varscan2
- RIF1 | c.6615C>G p.S2205= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV99690858; called by muse, mutect2, varscan2
- RIMS2 | c.2610A>G p.P870= (on ENST00000666250 / NM_001348490.2; = p.P678= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99155711; called by muse, mutect2, varscan2
- RIPPLY2 | c.135C>A p.G45= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100860751, COSV63762728; called by muse, mutect2, varscan2
- RTP2 | c.255C>A p.G85= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1327610336, COSV100832975; called by muse, mutect2, varscan2
- SCPEP1 | c.648G>T p.L216= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99227927; called by muse, mutect2, varscan2
- SCYL2 | c.1539A>G p.G513= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100675252; called by muse, mutect2, varscan2
- SECISBP2L | c.2145G>A p.R715= (on ENST00000559471 / NM_001193489.2; = p.R670= on NM_014701.4) | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99960613; called by muse, mutect2, varscan2
- SLC35C1 | c.258G>C p.L86= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100029428; called by muse, mutect2, varscan2
- SLC7A14 | c.864T>A p.A288= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV99200661; called by muse, mutect2
- SMAD6 | c.1005G>A p.A335= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs371677565; called by muse, mutect2, varscan2
- SPATA31E1 | c.3372C>T p.G1124= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs1031107851, COSV100350691; called by muse, mutect2, varscan2
- SYNE2 | c.6066C>T p.Y2022= | Silent (SNP) | VAF 89/122 reads (73%) | catalogued as COSV100648101; called by muse, mutect2, varscan2
- SYNE2 | c.8598G>T p.T2866= | Silent (SNP) | VAF 82/106 reads (77%) | catalogued as COSV100647028, COSV100648102; called by muse, mutect2, varscan2
- SYT6 | c.849C>A p.T283= (on ENST00000610222 / NM_001366225.1; = p.T198= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as COSV101059622, COSV65774192; called by muse, mutect2, varscan2
- TAL1 | c.825G>A p.A275= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs769810586, COSV53745893; called by muse, mutect2, varscan2
- TAS2R13 | c.702G>A p.V234= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV101183752; called by muse, mutect2, varscan2
- THSD7A | c.1998G>T p.L666= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV101448796; called by muse, mutect2, varscan2
- TSGA13 | c.345T>C p.S115= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV100746856; called by muse, mutect2, varscan2
- TUBA1B | c.921T>A p.P307= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as rs766975406, COSV100254173; called by muse, mutect2, varscan2
- VCAN | c.3963C>T p.D1321= | Silent (SNP) | VAF 41/74 reads (55%) | catalogued as rs764986668, COSV99426489; called by muse, mutect2, varscan2
- VPS13B | c.1053C>T p.S351= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV100662633; called by muse, mutect2, varscan2
- VTCN1 | c.714C>A p.I238= | Silent (SNP) | VAF 57/193 reads (30%) | catalogued as COSV100061989; called by muse, mutect2, varscan2
- WDR72 | c.1203G>T p.G401= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV100854781; called by muse, mutect2, varscan2
- XPO6 | c.915C>T p.R305= | Silent (SNP) | VAF 50/234 reads (21%) | catalogued as rs775990467, COSV100485185; called by muse, mutect2, varscan2
- ZAN | c.1356C>T p.F452= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs768779642, COSV61805332; called by muse, mutect2, varscan2
- ZFHX4 | c.9777C>A p.G3259= | Silent (SNP) | VAF 62/358 reads (17%) | catalogued as rs778232576, COSV50533655, COSV99264932; called by muse, mutect2, varscan2
- ZNF831 | c.4563G>A p.G1521= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV64037354; called by muse, mutect2, varscan2
- ZNF835 | c.630C>A p.T210= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV101606374; called by muse, mutect2, varscan2
- CSPP1 | c.534+111A>G | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- EIF5A2 | c.*1A>T | 3'UTR (SNP) | VAF 27/175 reads (15%) | catalogued as COSV99858728; called by muse, mutect2, varscan2
- FOXM1 | c.1267-1699C>T | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as rs750051225, COSV100700814; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.180A>T | RNA (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2
- PPM1K | c.542-2161G>T | Intron (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99901067; called by muse, mutect2, varscan2
- PRR14L | chr22:31676859 T>C | 3'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as rs369727426; called by muse, varscan2
- VKORC1 | c.173+286G>A | Intron (SNP) | VAF 188/1021 reads (18%) | catalogued as rs748589816, COSV100161805; called by muse, mutect2, varscan2
